Somatic mutation profile of tumor specimen TCGA-LP-A4AV-01A (aliquot TCGA-LP-A4AV-01A-11D-A243-09) from TCGA case TCGA-LP-A4AV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2.
Specimen TCGA-LP-A4AV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa8ec26c-2445-4ad7-9f50-23d8651d3279.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LP-A4AV-10A (Blood Derived Normal), aliquot TCGA-LP-A4AV-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57b4bf57-4c55-4fcf-b863-89c76434378e

The open-access MAF lists 430 somatic variants for this specimen: 313 protein-altering or splice-affecting, 104 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 271, Silent 104, Nonsense Mutation 30, 5'Flank 8, Splice Site 5, Frame Shift Ins 3, Nonstop Mutation 2, 3'UTR 2, Frame Shift Del 2, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL3 | c.3106C>T p.R1036* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as rs1131691668, COSV52482211; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD7 | c.3232C>T p.H1078Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1064795519, COSV71111200; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 13/25 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TJP2 | c.2632C>T p.Q878* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs1554667607, COSV55275538; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAK1 | c.2327C>G p.S776C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV68647077; called by muse, mutect2, varscan2
- ABCB1 | c.2734C>G p.Q912E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV55965528; called by muse, mutect2, varscan2
- ABCC11 | c.2472C>A p.F824L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV62326352; called by muse, mutect2, varscan2
- AC105001.2 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV59111437; called by muse, mutect2, varscan2
- ACP7 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV58701142; called by muse, mutect2, varscan2
- ACSL3 | c.1082C>G p.S361C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62484381, COSV62485085; called by muse, mutect2, varscan2
- ACSM3 | c.1740G>C p.K580N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV55504605, COSV99184002; called by muse, mutect2, varscan2
- ACTN3 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.048); catalogued as COSV101557910; called by muse, mutect2, varscan2
- AGFG2 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53547536; called by muse, mutect2, varscan2
- AKT2 | c.1278C>G p.F426L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV60907498, COSV60910689; called by muse, mutect2, varscan2
- ALG8 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100220095, COSV55203509; called by muse, mutect2
- AMOTL1 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs373426236; called by muse, mutect2
- APLP1 | c.1081C>G p.L361V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV55707466; called by muse, mutect2, varscan2
- AREL1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV62668368; called by muse, mutect2, varscan2
- ARHGAP27 | c.2110G>C p.E704Q (on ENST00000428638 / NM_001282290.1; = p.E363Q on NM_199282.3) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as COSV65358950; called by muse, mutect2, varscan2
- ARHGAP27 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV51818618; called by muse, mutect2, varscan2
- ARHGAP35 | c.4173G>C p.M1391I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68336340; called by muse, mutect2, varscan2
- ARHGAP4 | c.1530G>C p.E510D | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV63133250, COSV63134924; called by muse, mutect2, varscan2
- ARHGEF10L | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748277197, COSV51434350; called by muse, mutect2, varscan2
- ARHGEF12 | c.3509C>A p.S1170* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV63102858, COSV63107870; called by muse, mutect2, varscan2
- ARHGEF17 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs769100884, COSV55230794; called by muse, mutect2, varscan2
- ARMC8 | c.1256G>A p.R419Q (on ENST00000469044 / NM_001363941.2; = p.R405Q on NM_015396.6) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV58618205; called by muse, mutect2, varscan2
- ARMC8 | c.1540G>A p.E514K (on ENST00000469044 / NM_001363941.2; = p.E500K on NM_015396.6) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.899); catalogued as COSV58622524, COSV58623158; called by muse, mutect2, varscan2
- ART4 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV57453528; called by muse, mutect2, varscan2
- ASXL2 | c.3454C>G p.L1152V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV55469299; called by muse, mutect2, varscan2
- ATL3 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV60298645; called by muse, mutect2, varscan2
- ATP6V1E2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV60576777; called by muse, mutect2, varscan2
- ATRIP | c.1663C>G p.H555D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.372); catalogued as COSV56498258; called by muse, mutect2, varscan2
- BACH1 | c.1888C>G p.L630V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV54521553; called by muse, mutect2
- BAD | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs770729654, COSV57404276; called by muse, mutect2, varscan2
- BCAS3 | c.2468C>G p.S823* (on ENST00000390652 / NM_001353144.2; = p.S808* on NM_017679.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV66783574; called by mutect2, varscan2
- BCORL1 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV99501212; called by muse, mutect2, varscan2
- BCORL1 | c.4008G>C p.K1336N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1187104407, COSV54409349; called by muse, mutect2, varscan2
- BICRAL | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58408937; called by muse, mutect2, varscan2
- BPTF | c.2756C>T p.S919L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV58847418; called by muse, mutect2
- C1orf127 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.012); catalogued as rs746252512, COSV65439283; called by muse, mutect2, varscan2
- C1orf141 | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.582); catalogued as COSV63993474; called by muse, mutect2
- C2 | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54962962; called by muse, mutect2, varscan2
- C9orf50 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs747635774, COSV65252894; called by muse, mutect2, varscan2
- CAD | c.4099G>C p.E1367Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.913); catalogued as COSV53027850, COSV53032773; called by muse, mutect2, varscan2
- CASC3 | c.1940C>G p.P647R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52869756; called by muse, mutect2, varscan2
- CBL | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV50670912; called by muse, mutect2, varscan2
- CCDC142 | c.1393C>G p.L465V (on ENST00000393965 / NM_001365575.2; = p.L458V on NM_032779.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1434353551, COSV51779673, COSV51780313; called by muse, mutect2, varscan2
- CCDC33 | c.547-1G>A p.X183_splice | Splice Site (SNP) | VAF 15/31 reads (48%) | catalogued as COSV58359230; called by muse, mutect2, varscan2
- CCDC7 | c.3342G>C p.K1114N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV56553404; called by muse, mutect2, varscan2
- CCDC88C | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV66242517; called by muse, mutect2, varscan2
- CDH23 | c.9955G>A p.E3319K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.89); PolyPhen possibly damaging (0.562); catalogued as rs771858198, COSV56494268; called by mutect2, varscan2
- CEACAM7 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs199608746, COSV50073584; called by muse, mutect2, varscan2
- CFH | c.3131G>C p.R1044T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV66414508; called by muse, mutect2, varscan2
- CHIA | c.741G>A p.M247I (on ENST00000343320; = p.M139I on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as rs1307520569, COSV58478859; called by muse, mutect2, varscan2
- CHST12 | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV51678317; called by muse, mutect2, varscan2
- CHST12 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562521489, COSV51678329; called by muse, mutect2, varscan2
- CIC | c.2849C>T p.S950L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); catalogued as COSV50546926, COSV50546969; called by muse, mutect2, varscan2
- CLSTN2 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as COSV101515676, COSV71725689; called by muse, mutect2, varscan2
- CNIH4 | c.408G>C p.L136F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64796690; called by muse, mutect2, varscan2
- CNTNAP2 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV62268412; called by muse, mutect2, varscan2
- CNTRL | c.4132G>C p.E1378Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.558); catalogued as COSV53054556; called by muse, mutect2, varscan2
- COL21A1 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as COSV55180927, COSV55182616; called by muse, mutect2, varscan2
- COL6A6 | c.3763G>C p.E1255Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as COSV62030155; called by muse, mutect2, varscan2
- COMP | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750428025, COSV55876762; called by muse, mutect2, varscan2
- CPLANE1 | c.8930C>T p.S2977L | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV57072198; called by muse, mutect2, varscan2
- CPS1 | c.91T>A p.F31I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV51826918; called by muse, mutect2, varscan2
- CRISPLD1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV51553694; called by muse, mutect2, varscan2
- CTSO | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs1294822284, COSV70808884, COSV70809871; called by muse, mutect2, varscan2
- CUL2 | c.223-1G>A p.X75_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | catalogued as COSV66079696, COSV66081491; called by muse, mutect2
- CXorf65 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV52150476; called by muse, mutect2, varscan2
- CYP2C18 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV53675638; called by muse, mutect2, varscan2
- DBH | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.22); catalogued as rs377299166; called by mutect2, varscan2
- DENND4A | c.1468G>C p.D490H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71267202; called by muse, mutect2, varscan2
- DENND4B | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63412401; called by muse, varscan2
- DGKQ | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs746686910, COSV56620027; called by muse, mutect2, varscan2
- DHX57 | c.3572G>T p.G1191V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.238); catalogued as COSV54892155; called by muse, mutect2, varscan2
- DIP2B | c.4246G>A p.D1416N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV56593484; called by muse, mutect2, varscan2
- DLGAP5 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV55965714, COSV99904146; called by muse, mutect2, varscan2
- DMBT1 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371683770; called by muse, mutect2, varscan2
- DMBT1 | c.7030C>T p.H2344Y (on ENST00000338354 / NM_001377530.1; = p.H1587Y on NM_004406.3) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV57543302; called by muse, mutect2, varscan2
- DNAH3 | c.3118C>T p.Q1040* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV54511194; called by muse, varscan2
- DNAJC6 | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV54782932; called by muse, mutect2, varscan2
- DSG1 | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV57140054; called by muse, mutect2
- DSG3 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57130252; called by muse, mutect2
- DSP | c.2956C>T p.Q986* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as CM1310184, COSV101131397, COSV65793042; called by muse, mutect2, varscan2
- DST | c.17925G>C p.Q5975H (on ENST00000361203 / NM_001374722.1; = p.Q3672H on NM_015548.5) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV55045402; called by muse, mutect2, varscan2
- DUSP29 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs200532912, COSV100633427; called by muse, mutect2, varscan2
- DZIP1 | c.2543C>G p.S848* (on ENST00000347108; = p.S829* on NM_014934.5) | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100176073, COSV54826621; called by muse, mutect2, varscan2
- EDC4 | c.3943C>T p.Q1315* | Nonsense Mutation (SNP) | VAF 10/16 reads (63%) | catalogued as COSV59303021; called by muse, mutect2, varscan2
- EPHB4 | c.2479C>G p.Q827E | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62270850; called by muse, mutect2, varscan2
- EPHB6 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs752550289, COSV67421223; called by muse, mutect2, varscan2
- EPPK1 | c.4060C>T p.P1354S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV73262474; called by muse, mutect2, varscan2
- ESF1 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.156); catalogued as COSV52524966; called by muse, mutect2, varscan2
- ETNK1 | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV56890262; called by muse, mutect2, varscan2
- EVA1A | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs780949177, COSV52063097; called by muse, mutect2, varscan2
- FAM120A | c.1466C>G p.S489* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV52912312; called by muse, mutect2, varscan2
- FAM13A | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV52014722; called by muse, mutect2
- FAM153B | c.600G>C p.Q200H (on ENST00000253490; = p.Q123H on NM_001265615.1) | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as COSV53689022; called by muse, mutect2, varscan2
- FAM184A | c.2524C>T p.Q842* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV58859356; called by muse, mutect2, varscan2
- FAM217A | c.235-1G>A p.X79_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV51163223; called by muse, mutect2, varscan2
- FAM81B | c.657-1G>C p.X219_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV51987441; called by muse, mutect2, varscan2
- FAM83C | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.11); catalogued as rs373959129, COSV65584804; called by muse, mutect2, varscan2
- FAT3 | c.12833G>A p.R4278Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV53184868; called by muse, mutect2, varscan2
- FBXW12 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV56485835; called by muse, mutect2, varscan2
- FCGBP | c.6911G>C p.G2304A | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.408); catalogued as rs748312278, COSV55457908; called by muse, mutect2, varscan2
- FEM1B | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60989944; called by muse, mutect2, varscan2
- FGD3 | c.1742G>A p.R581K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV61600406; called by muse, mutect2, varscan2
- FILIP1 | c.446C>A p.S149* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as rs139907750, COSV52733311, COSV52742497; called by muse, mutect2, varscan2
- FLNC | c.7921C>T p.R2641W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as rs750629528, COSV50800240; called by muse, mutect2, varscan2
- FMR1 | c.1666C>T p.H556Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.26); catalogued as COSV54428027, COSV99502969; called by muse, mutect2, varscan2
- FOXD4 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1468001517, COSV58703644; called by muse, mutect2, varscan2
- FRMD4A | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52738002; called by muse, mutect2, varscan2
- FSD2 | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1427658680, COSV58013611; called by muse, mutect2, varscan2
- GAD1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.9); catalogued as COSV60154482; called by muse, mutect2, varscan2
- GAS2L3 | c.1163C>G p.S388* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs1459978010, COSV57156586, COSV57159424; called by muse, mutect2, varscan2
- GGA1 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV57332143; called by muse, mutect2, varscan2
- GOLGB1 | c.2652G>C p.E884D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.231); catalogued as COSV61462390, COSV61472125; called by muse, mutect2, varscan2
- GTF2H4 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV52561562; called by muse, mutect2, varscan2
- H1-5 | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV58898801; called by muse, mutect2, varscan2
- HAL | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781581441, COSV54120752; called by muse, mutect2, varscan2
- HES1 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV51685716; called by muse, mutect2, varscan2
- HFM1 | c.1050G>A p.W350* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV54038838; called by mutect2, varscan2
- HKDC1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63579938; called by muse, mutect2, varscan2
- HMCN1 | c.6493C>T p.Q2165* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV54947972, COSV99630322; called by muse, mutect2
- HRAS | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV54248437; called by muse, mutect2, varscan2
- HSD17B10 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51449055; called by muse, mutect2, varscan2
- HSPA12B | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.716); catalogued as COSV54769541, COSV99654003; called by muse, mutect2, varscan2
- HTR2C | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.974); catalogued as COSV52226761; called by muse, mutect2, varscan2
- HTRA3 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV100246591; called by muse, mutect2, varscan2
- IL5RA | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV56527273; called by muse, mutect2, varscan2
- INTS6 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1420554925, COSV60881018; called by muse, mutect2, varscan2
- IPO13 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV64895383; called by muse, mutect2, varscan2
- IPO4 | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs201767926; called by muse, mutect2, varscan2
- ITGA4 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52002207; called by muse, mutect2, varscan2
- ITGB3 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs1241947599, COSV71385350; called by muse, mutect2, varscan2
- KALRN | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV53782540; called by muse, mutect2, varscan2
- KAT7 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52012964; called by muse, mutect2, varscan2
- KDELR1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); catalogued as rs769954207, COSV58103097; called by muse, mutect2, varscan2
- KDM6A | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV65047204; called by muse, mutect2, varscan2
- KIF7 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV67999799; called by muse, mutect2, varscan2
- KLF15 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV56179126; called by muse, mutect2, varscan2
- KLF6 | c.660C>A p.H220Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51496484; called by muse, mutect2, varscan2
- KLHL7 | c.403G>C p.D135H (on ENST00000339077 / NM_001031710.3; = p.D87H on NM_018846.5) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV59165235; called by muse, mutect2
- LAMA1 | c.3574G>A p.E1192K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs368852040; called by muse, mutect2, varscan2
- LARP4 | c.1349G>A p.R450K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1209037766, COSV53319902; called by muse, mutect2, varscan2
- LDHC | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs372373685, COSV55006354; called by muse, mutect2, varscan2
- LINGO1 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV62438879; called by muse, mutect2, varscan2
- LLGL2 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs199973131, COSV51418079; called by muse, mutect2
- LMBR1L | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57267397, COSV57268302; called by muse, mutect2, varscan2
- LMOD3 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748378652, COSV70456921; called by muse, mutect2, varscan2
- LPCAT1 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV52036725, COSV52041892; called by muse, mutect2, varscan2
- LRCH2 | c.2281C>T p.Q761* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV57749816, COSV57761589; called by muse, mutect2, varscan2
- LRP1B | c.11899G>C p.E3967Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.419); catalogued as COSV67205940, COSV67282561; called by muse, mutect2, varscan2
- LRRTM3 | c.509G>C p.R170T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.101); catalogued as COSV63672892; called by muse, mutect2, varscan2
- M1AP | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51845580; called by mutect2, varscan2
- MALT1 | c.1423C>G p.P475A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.217); catalogued as rs1568151633, COSV61936902; called by muse, mutect2, varscan2
- MAP7D3 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201460312, COSV60170503; called by muse, mutect2, varscan2
- MCHR1 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs200469291, COSV50763349; called by muse, mutect2, varscan2
- MED18 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65791127; called by muse, mutect2, varscan2
- MFAP4 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV55192180; called by muse, mutect2, varscan2
- MFSD8 | c.244T>C p.S82P | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV56553267; called by muse, mutect2, varscan2
- MGA | c.8050C>G p.L2684V (on ENST00000219905 / NM_001164273.1; = p.L2475V on NM_001080541.2) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV54964579; called by muse, mutect2, varscan2
- MLEC | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV57330581; called by muse, varscan2
- MNDA | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751266784, COSV63740840; called by muse, mutect2, varscan2
- MOV10 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747208248, COSV53517225; called by muse, mutect2, varscan2
- MOV10L1 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53180957; called by muse, varscan2
- MROH2B | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV68190354; called by muse, mutect2, varscan2
- MSH4 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54214086; called by muse, mutect2, varscan2
- MST1R | c.4113G>T p.M1371I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as COSV56574988; called by muse, varscan2
- MUC16 | c.17336C>G p.S5779C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV67500077; called by muse, mutect2
- MUC16 | c.17183C>G p.S5728C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs866944888, COSV67444191, COSV67500083; called by muse, mutect2, varscan2
- MUC16 | c.16577C>G p.S5526C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as rs1384654072, COSV101202061; called by muse, mutect2, varscan2
- MUC16 | c.16417C>T p.Q5473* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV67453878, COSV67462441; called by muse, mutect2, varscan2
- MUC16 | c.16079C>T p.S5360F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV101202137, COSV67500091; called by muse, varscan2
- MUC16 | c.16001C>G p.S5334C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as COSV67450102, COSV67500098; called by muse, varscan2
- MUC16 | c.15866C>T p.S5289L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV67500107; called by muse, mutect2, varscan2
- MUC16 | c.15521C>A p.S5174Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.635); catalogued as COSV67442842, COSV67500116; called by muse, mutect2
- MUC16 | c.15032C>T p.S5011L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.205); catalogued as COSV67453182; called by muse, mutect2
- MUC16 | c.14846C>A p.S4949* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV67500126, COSV99064217; called by muse, mutect2, varscan2
- MUC16 | c.14723C>T p.S4908L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs753011569, COSV67447298; called by muse, mutect2, varscan2
- MUC16 | c.13790C>T p.S4597F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV67454317; called by muse, mutect2, varscan2
- MUC16 | c.13594C>A p.H4532N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.139); catalogued as rs750358611, COSV67494392, COSV67500148; called by muse, mutect2, varscan2
- MYH13 | c.4375G>T p.E1459* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV52845711, COSV99352331; called by muse, mutect2, varscan2
- MYO7B | c.2801C>T p.S934L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs749423442, COSV67345356; called by muse, mutect2, varscan2
- N4BP2 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV54707891; called by muse, varscan2
- NECTIN1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163551430, COSV50610016; called by muse, mutect2
- NFASC | c.1076G>A p.R359Q (on ENST00000339876 / NM_001378329.1; = p.R370Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs767453033, COSV58366173; called by muse, mutect2, varscan2
- NID1 | c.419G>T p.R140I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV51621476, COSV51630192; called by muse, mutect2, varscan2
- NONO | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52140818; called by muse, mutect2, varscan2
- NR2C2AP | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV57395279; called by muse, mutect2, varscan2
- NR2E1 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.796); catalogued as COSV100934585, COSV64562160; called by muse, mutect2, varscan2
- NR3C1 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.052); catalogued as COSV51547112; called by muse, mutect2, varscan2
- NRAS | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.562); catalogued as COSV54762820; called by muse, mutect2, varscan2
- NRBP1 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51996431; called by muse, mutect2, varscan2
- NSFL1C | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99401677; called by mutect2, varscan2
- NUBPL | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55277025; called by muse, mutect2, varscan2
- NUGGC | c.2131C>A p.Q711K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV58439994; called by muse, mutect2, varscan2
- NUMA1 | c.5188G>A p.E1730K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as rs1407048322, COSV59643034; called by muse, mutect2, varscan2
- NUP205 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.089); catalogued as COSV53654837, COSV53667305; called by muse, mutect2, varscan2
- ODF4 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.154); catalogued as COSV60273238; called by muse, mutect2, varscan2
- OLIG2 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.066); catalogued as rs1171484068, COSV60973501; called by muse, mutect2, varscan2
- OR4E2 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57731953, COSV57732417; called by muse, mutect2, varscan2
- ORC1 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as COSV65365422; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.620G>C p.R207T (on ENST00000259318 / NM_001136562.3; = p.R438T on NM_007203.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.068); catalogued as COSV52182389; called by muse, mutect2, varscan2
- PATJ | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV57173438; called by muse, mutect2
- PCDHB5 | c.352del p.Q118Kfs*9 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as COSV50650088; called by mutect2, varscan2
- PCMTD2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55060806; called by muse, mutect2, varscan2
- PDCD6IP | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV56246307, COSV56246473; called by muse, mutect2, varscan2
- PDS5B | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV59735663; called by muse, mutect2, varscan2
- PEG3 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs767795478, COSV55637650, COSV55650451; called by muse, mutect2, varscan2
- PHF8 | c.311C>T p.S104F (on ENST00000357988 / NM_001184896.1; = p.S68F on NM_015107.3) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV57689060; called by muse, mutect2, varscan2
- PIGU | c.880C>G p.Q294E | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54167505; called by muse, mutect2, varscan2
- PIK3C2B | c.3742G>A p.D1248N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV65814683; called by muse, mutect2, varscan2
- PLCD3 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as rs1337870768, COSV59563454; called by muse, mutect2, varscan2
- PLEKHA4 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV54366846; called by muse, mutect2, varscan2
- PLIN4 | c.752C>G p.T251R (on ENST00000301286; = p.T266R on NM_001367868.2) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV56688330, COSV56700064; called by muse, mutect2, varscan2
- PLXNB3 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as rs1557059521, COSV62803086; called by muse, mutect2, varscan2
- POLR1H | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60138172, COSV60138818; called by muse, mutect2, varscan2
- PPFIA2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99048593; called by muse, mutect2, varscan2
- PPP1CB | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.185); catalogued as COSV56092278; called by muse, mutect2, varscan2
- PPP1R9A | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs1417192736, COSV56914096; called by muse, mutect2
- PREX1 | c.3703C>G p.L1235V | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV64257607; called by muse, mutect2
- PRR13 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.72); PolyPhen probably damaging (0.997); catalogued as COSV65769407; called by muse, mutect2, varscan2
- PTK2B | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs373105458; called by muse, mutect2, varscan2
- PURA | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs1561793355, COSV58763135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAD54L | c.165G>C p.L55F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV64335856; called by muse, mutect2, varscan2
- REL | c.1722G>A p.M574I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1304799405, COSV54364468; called by muse, mutect2, varscan2
- RIMS1 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.732); catalogued as rs748212094, COSV53466796; called by muse, mutect2, varscan2
- RIPK4 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768158256, COSV60185763; called by muse, mutect2, varscan2
- RPS21 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.141); catalogued as COSV54158806; called by muse, mutect2, varscan2
- RRAD | c.333C>A p.F111L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV100234571; called by muse, mutect2
- RSBN1 | c.2025C>G p.I675M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV54731780; called by muse, mutect2
- RSBN1L | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1456614517, COSV58511584; called by muse, mutect2, varscan2
- RSPH4A | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.06); catalogued as COSV57637070; called by muse, mutect2, varscan2
- RTN2 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV55596446; called by muse, mutect2, varscan2
- SCAMP3 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV56947817; called by muse, mutect2, varscan2
- SCLT1 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55413872; called by muse, mutect2, varscan2
- SCN7A | c.2387C>G p.S796C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV69275254; called by muse, mutect2, varscan2
- SDR39U1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759354151, COSV52163973; called by muse, mutect2, varscan2
- SEMA4A | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as COSV61774335; called by muse, mutect2, varscan2
- SEMA4F | c.1502C>A p.S501Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV60285600; called by muse, mutect2, varscan2
- SF3B2 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV59430491; called by muse, mutect2, varscan2
- SGCA | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as rs780564461, COSV56248957; called by muse, mutect2, varscan2
- SGF29 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV57683395; called by muse, mutect2
- SGO1 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1039777962, COSV55425518; called by muse, mutect2, varscan2
- SLC27A2 | c.501G>C p.E167D | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.593); catalogued as COSV51064196; called by muse, mutect2, varscan2
- SLC49A4 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV53749995; called by muse, mutect2, varscan2
- SLC4A9 | c.1849C>T p.R617C (on ENST00000507527 / NM_001258428.2; = p.R593C on NM_031467.3) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs769781263, COSV50218642; called by muse, mutect2, varscan2
- SLC6A7 | c.482G>A p.W161* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as COSV57941054; called by muse, mutect2
- SMARCB1 | c.602C>G p.S201C (on ENST00000263121; = p.S247C on NM_003073.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.852); catalogued as COSV54103768; called by muse, mutect2, varscan2
- SND1 | c.1164G>C p.K388N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV61250548; called by muse, mutect2, varscan2
- SREBF2 | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1414875081, COSV63332966; called by muse, mutect2, varscan2
- SSX5 | c.467-1G>T p.X156_splice (on ENST00000347757 / NM_175723.1; = p.X197_splice on NM_021015.4) | Splice Site (SNP) | VAF 49/242 reads (20%) | catalogued as COSV61256104, COSV61256664; called by muse, mutect2, varscan2
- STAP2 | c.1103G>A p.R368K (on ENST00000594605 / NM_001013841.2; = p.R414K on NM_017720.3) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55699351; called by muse, mutect2, varscan2
- STK11IP | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.621); catalogued as rs1341223839, COSV55249758; called by muse, mutect2, varscan2
- STK3 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV69227685; called by muse, mutect2, varscan2
- SUFU | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.762); catalogued as rs1240436102, COSV64016548; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUMF1 | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as rs1209016416, COSV55996551; called by muse, mutect2, varscan2
- SYCP1 | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV65701523; called by muse, mutect2, varscan2
- SYNE2 | c.15410G>A p.R5137K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV100648023, COSV59973332; called by muse, mutect2, varscan2
- TAF1 | c.3602G>A p.R1201Q (on ENST00000373790 / NM_138923.4; = p.R1222Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs1299734627, COSV52109641; called by muse, mutect2, varscan2
- TAF4 | c.1702C>T p.Q568* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV53343265; called by muse, mutect2, varscan2
- TBC1D1 | c.3212C>T p.S1071F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs764538051, COSV54728539; called by muse, mutect2, varscan2
- TBC1D21 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.107); catalogued as COSV55997118; called by muse, mutect2, varscan2
- TBC1D9 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1167259343, COSV71309434; called by muse, mutect2, varscan2
- TCF20 | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59496872; called by muse, mutect2, varscan2
- TCN2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV53191763; called by muse, mutect2, varscan2
- TCOF1 | c.1441G>A p.E481K (on ENST00000377797 / NM_001135243.1; = p.E404K on NM_000356.4) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV60355550; called by muse, varscan2
- TCTEX1D4 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1403248688, COSV59501446; called by muse, mutect2, varscan2
- TEAD4 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63282745; called by muse, mutect2, varscan2
- THSD4 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV55987267; called by muse, mutect2, varscan2
- TIGAR | c.254C>G p.S85* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV51630124; called by muse, mutect2, varscan2
- TLN2 | c.6798C>G p.F2266L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs764058761, COSV60896993; called by muse, mutect2, varscan2
- TMEM54 | c.668G>C p.*223Sext*57 | Nonstop Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as rs1557543405, COSV61276521; called by muse, mutect2, varscan2
- TMX1 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as COSV63335637; called by muse, mutect2
- TREM1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV55149784; called by muse, varscan2
- TRIOBP | c.4526G>C p.R1509T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.025); catalogued as COSV60383942, COSV60385535; called by muse, mutect2, varscan2
- TRIOBP | c.5044G>A p.E1682K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.196); catalogued as rs773664934, COSV60385542; called by muse, mutect2, varscan2
- TRIOBP | c.5408C>G p.S1803C (on ENST00000644935 / NM_001039141.3; = p.S90C on NM_007032.5) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as rs765107583, COSV58526380; called by muse, mutect2, varscan2
- TRPC4 | c.1212G>A p.W404* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV59022282; called by muse, mutect2, varscan2
- TSPAN7 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV54534924; called by muse, mutect2, varscan2
- TTN | c.102386G>A p.G34129E (on ENST00000591111; = p.G26705E on NM_003319.4) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | PolyPhen probably damaging (1); catalogued as COSV60399225; called by muse, mutect2, varscan2
- TUBD1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs756379982, COSV57874886; called by muse, mutect2, varscan2
- TWF2 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751974151, COSV59727901; called by muse, mutect2, varscan2
- UBA5 | c.1215G>C p.*405Yext*12 | Nonstop Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV53906793; called by muse, mutect2, varscan2
- UHRF1BP1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51961319; called by muse, mutect2, varscan2
- UNC5D | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV54842436; called by muse, mutect2, varscan2
- UPF3B | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52232212; called by muse, mutect2, varscan2
- USH2A | c.3304C>T p.Q1102* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV56450221; called by muse, mutect2, varscan2
- USP11 | c.457G>A p.E153K (on ENST00000218348; = p.E110K on NM_001371072.1) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as rs753381678, COSV54476400; called by muse, mutect2, varscan2
- USP19 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as COSV60049105; called by muse, varscan2
- USP46 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV71513204; called by muse, mutect2, varscan2
- VPS13A | c.5163G>A p.M1721I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1470990131, COSV62440683; called by muse, mutect2, varscan2
- VPS13D | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV62535261; called by muse, mutect2, varscan2
- WNK4 | c.2414C>G p.S805C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV55911270; called by muse, mutect2, varscan2
- ZBTB38 | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58544736; called by muse, mutect2, varscan2
- ZDHHC5 | c.1249C>G p.H417D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV54709589; called by muse, mutect2, varscan2
- ZFAT | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV64748693; called by muse, mutect2, varscan2
- ZMYM2 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs375763195, COSV67038169; called by muse, mutect2, varscan2
- ZNF407 | c.2810C>T p.S937L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1272151126, COSV55273429; called by muse, mutect2, varscan2
- ZNF496 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs781476350, COSV54176904, COSV54182903; called by muse, mutect2, varscan2
- ZNF577 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV56818247; called by muse, mutect2, varscan2
- ZNF605 | c.1815G>A p.M605I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59160126; called by muse, mutect2, varscan2
- ZNF615 | c.444G>C p.R148S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV65033835, COSV65035223; called by muse, mutect2, varscan2
- ZNF621 | c.513G>C p.M171I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV59459399; called by muse, mutect2, varscan2
- ZNF839 | c.1043C>T p.S348L (on ENST00000558850 / NM_001267827.1; = p.S464L on NM_018335.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as rs960378496, COSV51760039; called by muse, mutect2, varscan2
- B4GALNT3 | c.1279del p.E427Kfs*4 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- CLSTN1 | c.1284C>G p.I428M (on ENST00000377298 / NM_001009566.3; = p.I418M on NM_014944.4) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2
- NENF | c.504_505insGA p.K169Efs*23 | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | called by mutect2, varscan2*
- TSPAN31 | c.78G>T p.L26F | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TTLL5 | c.151dup p.T51Nfs*7 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- ZNF750 | c.778dup p.L260Pfs*8 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- ADAMTS7 | c.1653A>T p.S551= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV66309696; called by muse, mutect2, varscan2
- ADARB2 | c.42G>A p.L14= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs372889691; called by muse, mutect2, varscan2
- ADCY10 | c.2001C>T p.F667= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV63245656; called by muse, mutect2, varscan2
- ADGRV1 | c.12015G>A p.L4005= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV67996775; called by muse, mutect2, varscan2
- ADRA2A | c.1356C>T p.F452= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV54528889; called by muse, mutect2, varscan2
- AEBP1 | c.2115C>G p.L705= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV56261822; called by muse, mutect2, varscan2
- AP1M1 | c.864C>T p.H288= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99358713; called by muse, mutect2, varscan2
- ARHGEF12 | c.1647C>G p.L549= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV63107864; called by muse, varscan2
- ARHGEF15 | c.669C>G p.L223= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV62726825; called by muse, mutect2, varscan2
- ART4 | c.723C>G p.L241= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV57453520; called by muse, mutect2, varscan2
- ASB13 | c.567G>A p.A189= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV63092416; called by muse, mutect2, varscan2
- BRCA1 | c.4800G>A p.L1600= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV58796135; called by muse, mutect2
- C3 | c.4506G>A p.L1502= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV55582696; called by muse, mutect2, varscan2
- CCDC97 | c.642G>A p.G214= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs903128254, COSV54191890; called by muse, mutect2, varscan2
- CD177 | c.339C>T p.L113= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV65120831; called by mutect2, varscan2
- CDK8 | c.354G>A p.K118= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV101037701; called by muse, mutect2, varscan2
- CENPF | c.5859C>G p.L1953= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV65276162, COSV65279812; called by muse, mutect2, varscan2
- CFAP69 | c.1008G>A p.L336= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV60185866, COSV60188997; called by muse, mutect2, varscan2
- CNDP1 | c.1380C>A p.I460= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs774635198, COSV62593188, COSV62595636; called by muse, mutect2, varscan2
- COL11A1 | c.552G>A p.K184= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100618280, COSV62201699; called by muse, mutect2, varscan2
- COL1A1 | c.3726C>T p.I1242= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs768572265, COSV56803195; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP2F1 | c.1143G>A p.L381= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100463084; called by muse, mutect2, varscan2
- DAB2IP | c.2157C>T p.V719= (on ENST00000408936; = p.V691= on NM_032552.3) | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs944327306, COSV52269685; called by muse, mutect2, varscan2
- DGKQ | c.1422C>T p.I474= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99893196; called by muse, mutect2, varscan2
- EEF2K | c.774C>T p.F258= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1353138460, COSV53787877; called by muse, mutect2, varscan2
- EPAS1 | c.441G>C p.L147= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs1470742039, COSV55388883; called by muse, mutect2, varscan2
- FAHD2A | c.51G>A p.Q17= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV51977670; called by muse, mutect2, varscan2
- FAM117B | c.1248A>G p.T416= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV57422848; called by muse, mutect2, varscan2
- GATB | c.51C>T p.F17= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs757217781, COSV56129302, COSV56131138; called by muse, mutect2, varscan2
- GEMIN4 | c.2949C>T p.F983= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV56746457, COSV56747861; called by muse, mutect2, varscan2
- GJB3 | c.69C>T p.I23= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as COSV64904902; called by muse, mutect2, varscan2
- GLS2 | c.411G>C p.V137= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV61738572; called by muse, mutect2, varscan2
- GPRC5B | c.63C>T p.F21= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1274487360, COSV56026112; called by muse, mutect2, varscan2
- GRK7 | c.594G>T p.G198= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV53825848; called by muse, mutect2
- GTF2E2 | c.669C>T p.V223= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV63479285; called by muse, mutect2, varscan2
- HIVEP3 | c.3453C>T p.L1151= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs1207391900, COSV56025272; called by muse, mutect2, varscan2
- HLA-F | c.192G>A p.P64= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs755920765, COSV52577667; called by muse, mutect2, varscan2
- HTR2C | c.21G>A p.A7= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs202034357, COSV52201796, COSV99350501; called by muse, mutect2, varscan2
- IGHV1-45 | c.306G>A p.L102= | Silent (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- IL20 | c.24C>T p.F8= | Silent (SNP) | VAF 34/68 reads (50%) | catalogued as COSV65585261; called by muse, mutect2, varscan2
- ITPKA | c.1173G>A p.R391= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV53029649; called by muse, mutect2, varscan2
- ITPR1 | c.6279G>A p.S2093= (on ENST00000354582; = p.S2038= on NM_002222.7) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs771768628, COSV56967795; called by muse, mutect2, varscan2
- KCNJ9 | c.78G>A p.E26= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV63632566; called by muse, mutect2
- KIAA1109 | c.9411C>G p.L3137= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99185697; called by muse, mutect2, varscan2
- KLF6 | c.849C>G p.L283= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV51494355, COSV51496473; called by mutect2, varscan2
- LIMK2 | c.1554G>A p.L518= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV59184933; called by muse, mutect2, varscan2
- LRCH4 | c.1995C>T p.F665= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs746084308, COSV56166942; called by muse, mutect2, varscan2
- LRRC37A2 | c.4095G>A p.L1365= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV60236813; called by muse, mutect2, varscan2
- MOGS | c.1185C>T p.L395= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs751485436, COSV51972403; called by muse, mutect2, varscan2
- MORF4L1 | c.9G>A p.P3= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV58705935; called by muse, mutect2, varscan2
- MYO3A | c.525C>T p.L175= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV99781933; called by muse, mutect2, varscan2
- MYOC | c.378G>A p.R126= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV50680650; called by muse, mutect2, varscan2
- NPY2R | c.456C>T p.I152= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs892678229, COSV61527680; called by muse, mutect2, varscan2
- NUP205 | c.747C>T p.L249= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV53667292; called by muse, mutect2, varscan2
- P2RX1 | c.555C>T p.F185= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV56656267; called by muse, mutect2, varscan2
- PCDHGA9 | c.2127C>T p.I709= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99548820; called by muse, mutect2, varscan2
- PITX2 | c.759G>A p.L253= (on ENST00000354925 / NM_001204397.1; = p.L260= on NM_000325.6) | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV100146546; called by muse, mutect2, varscan2
- PLEKHG2 | c.3678C>T p.L1226= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1428075616, COSV99218316; called by muse, mutect2, varscan2
- PLEKHH3 | c.51C>T p.F17= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV53191600; called by muse, mutect2, varscan2
- PLPPR2 | c.591C>T p.L197= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs767395661, COSV52263032; called by mutect2, varscan2
- PNKP | c.906G>A p.K302= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1555811171, COSV55591083; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPARGC1B | c.1902C>T p.L634= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV58525998; called by muse, mutect2
- PROCR | c.411G>C p.G137= | Silent (SNP) | VAF 34/45 reads (76%) | catalogued as COSV53827025; called by muse, mutect2, varscan2
- PSMD13 | c.426C>T p.L142= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100728965; called by muse, mutect2, varscan2
- QARS1 | c.804C>T p.F268= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV60274570, COSV60275881; called by muse, mutect2, varscan2
- RALGDS | c.549C>T p.S183= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs370089103; called by muse, mutect2, varscan2
- RGS7 | c.234G>A p.A78= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs374423156; called by muse, mutect2, varscan2
- RIMS1 | c.186G>A p.A62= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs773456988, COSV53453239; called by mutect2, varscan2
- RPH3A | c.111C>A p.P37= (on ENST00000389385 / NM_001143854.2; = p.P33= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV66993341; called by muse, mutect2, varscan2
- RXFP4 | c.816G>A p.V272= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV58152199; called by muse, mutect2, varscan2
- RYR3 | c.3303C>T p.V1101= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs752550511, COSV66801263, COSV66810148; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR3 | c.4101G>A p.V1367= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV101215019; called by muse, mutect2, varscan2
- SDHB | c.549C>G p.L183= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV64965886; called by muse, mutect2, varscan2
- SFMBT1 | c.2487C>T p.L829= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV56258052; called by muse, mutect2, varscan2
- SGPL1 | c.1107G>A p.K369= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV64591694; called by muse, mutect2, varscan2
- SLC26A4 | c.261C>T p.D87= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs758057358, COSV55914824; called by muse, mutect2, varscan2
- SLC34A2 | c.1686C>T p.V562= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs114501307, COSV65943401; called by muse, mutect2, varscan2
- SLC35D1 | c.711C>T p.F237= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV99338582; called by muse, mutect2, varscan2
- SLC39A12 | c.2016G>A p.L672= (on ENST00000377369 / NM_001145195.2; = p.L635= on NM_152725.3) | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV66202015, COSV66203026; called by muse, mutect2, varscan2
- SLC5A9 | c.1317C>T p.V439= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV52586218; called by muse, mutect2, varscan2
- SMARCA5 | c.1515C>T p.F505= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV51644528; called by muse, mutect2, varscan2
- SMS | c.516G>A p.E172= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV101048317; called by muse, mutect2, varscan2
- SPHKAP | c.3318G>A p.L1106= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs749759407, COSV60897157; called by muse, varscan2
- STAB1 | c.5091G>C p.V1697= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV58744040; called by muse, varscan2
- STAB1 | c.5172G>A p.P1724= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs1457336752, COSV58744051; called by muse, varscan2
- STAC2 | c.900C>G p.L300= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV61065777, COSV61066972; called by muse, mutect2, varscan2
- STX8 | c.246C>G p.L82= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV60497241; called by muse, mutect2, varscan2
- SYT3 | c.1266C>T p.I422= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs780078886, COSV58899333; called by muse, mutect2, varscan2
- TCOF1 | c.1407G>T p.G469= (on ENST00000377797 / NM_001135243.1; = p.G392= on NM_000356.4) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV60355532; called by muse, varscan2
- TECPR2 | c.336G>C p.G112= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV63974824; called by muse, mutect2, varscan2
- TF | c.1098G>A p.L366= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53923511; called by muse, mutect2, varscan2
- THOC5 | c.1767G>A p.E589= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- TNXB | c.8967G>A p.L2989= (on ENST00000647633; = p.L2742= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1299863516, COSV100926212, COSV64490483; called by muse, mutect2, varscan2
- TRIOBP | c.4284G>A p.Q1428= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV60385527; called by muse, mutect2, varscan2
- TRIT1 | c.678C>T p.I226= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV57550527; called by muse, mutect2
- TRMT1 | c.114G>A p.E38= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs1251906614, COSV52836267; called by muse, mutect2, varscan2
- TRPM6 | c.1105C>T p.L369= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV62525057; called by muse, mutect2, varscan2
- TSSK2 | c.552C>T p.P184= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs185015956, COSV52816472; called by muse, mutect2, varscan2
- TTN | c.92019G>A p.K30673= (on ENST00000591111; = p.K23249= on NM_003319.4) | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs779796308, COSV60399288; called by muse, mutect2
- UPK3B | c.867C>T p.A289= (on ENST00000257632; = p.P261L on NM_001347684.2) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs751471783, COSV57537078; called by muse, mutect2, varscan2
- VPS13D | c.11457G>A p.K3819= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99169981; called by muse, mutect2, varscan2
- ZFYVE26 | c.6189C>T p.T2063= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs777612795, COSV61334360; called by muse, mutect2, varscan2
- ZGLP1 | c.678C>G p.L226= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs1471226134, COSV67059701; called by muse, mutect2, varscan2
- ZNF608 | c.1617G>A p.E539= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV60442071; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501350 C>G | 5'Flank (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502391 C>G | 5'Flank (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503114 C>T | 5'Flank (SNP) | VAF 11/40 reads (28%) | catalogued as rs1348979710; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504141 C>A | 5'Flank (SNP) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- AP000769.3 | chr11:65504458 C>T | 5'Flank (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504748 C>G | 5'Flank (SNP) | VAF 6/32 reads (19%) | catalogued as rs1200198901; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505552 C>G | 5'Flank (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- AP000769.3 | chr11:65505999 C>G | 5'Flank (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- CYHR1 | c.246+82G>A | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as COSV56763305; called by muse, mutect2, varscan2
- FAS | c.*107G>A | 3'UTR (SNP) | VAF 5/22 reads (23%) | catalogued as COSV58240073; called by muse, mutect2, varscan2
- LINC01565 | n.1214G>C | RNA (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- SEBOX | c.-39C>T | 5'UTR (SNP) | VAF 23/56 reads (41%) | catalogued as COSV52648537; called by muse, mutect2, varscan2
- XIRP2 | c.*461G>A | 3'UTR (SNP) | VAF 4/10 reads (40%) | catalogued as COSV54739473; called by muse, mutect2, varscan2
